Somatic mutation profile of tumor specimen TCGA-56-8626-01A (aliquot TCGA-56-8626-01A-11D-2395-08) from TCGA case TCGA-56-8626, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.0 years (21,908 days).
Specimen TCGA-56-8626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adc4f487-6a00-475b-b037-79b42b77e8cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8626-10A (Blood Derived Normal), aliquot TCGA-56-8626-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/578bb727-5254-46cf-a42a-87c82c1555e9

The open-access MAF lists 289 somatic variants for this specimen: 212 protein-altering or splice-affecting, 67 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 67, Nonsense Mutation 16, Splice Site 8, Frame Shift Del 7, Intron 7, Splice Region 3, Frame Shift Ins 2, 5'Flank 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs771961377, CM104336, COSV99650206; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.6594del p.Y2199Ifs*65 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs1555192751, CD114942; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADAM28 | c.1000G>C p.A334P | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740078; called by muse, mutect2, varscan2
- ADAMTS3 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 66/349 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as COSV99711063, COSV99712380; called by muse, mutect2, varscan2
- ADAR | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs763106489, COSV99426902; called by muse, mutect2, varscan2
- ADD1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1210145135, COSV99297186; called by muse, mutect2, varscan2
- ADGRE2 | c.2272G>A p.V758I | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV100216594; called by muse, mutect2, varscan2
- AHRR | c.709-2A>G p.X237_splice | Splice Site (SNP) | VAF 11/196 reads (6%) | catalogued as COSV100328152; called by muse, mutect2
- AKR1D1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99653327; called by muse, mutect2
- ALMS1 | c.8029G>T p.D2677Y | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100044081; called by muse, mutect2, varscan2
- ALPP | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101235203; called by muse, mutect2
- ANGPT4 | c.1104C>A p.H368Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV101124917; called by muse, mutect2, varscan2
- ANK3 | c.6130A>C p.S2044R | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV99782928; called by muse, mutect2, varscan2
- API5 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.096); catalogued as rs1012566540, COSV66633547; called by muse, mutect2, varscan2
- ARC | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100751802; called by muse, mutect2
- ARHGEF39 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100526383; called by muse, mutect2, varscan2
- ARMC1 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99395210; called by muse, mutect2, varscan2
- ASB18 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101293647; called by muse, varscan2
- ASCL1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99902191; called by muse, mutect2, varscan2
- ASIC5 | c.1235+1G>T p.X412_splice | Splice Site (SNP) | VAF 20/103 reads (19%) | catalogued as COSV101611189; called by muse, mutect2, varscan2
- ATP13A4 | c.1565C>G p.P522R | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99795371; called by muse, mutect2
- ATP1A3 | c.1216A>G p.T406A (on ENST00000545399 / NM_001256214.2; = p.T393A on NM_152296.5) | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV100132625; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2211C>G p.I737M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377220, COSV57751766; called by muse, mutect2, varscan2
- ATRNL1 | c.1579G>T p.V527F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100747136; called by muse, mutect2, varscan2
- BLM | c.3018G>A p.M1006I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100757368; called by muse, mutect2, varscan2
- BMP6 | c.1199C>A p.A400D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.211); catalogued as COSV99307576; called by muse, mutect2, varscan2
- BTN2A2 | c.871A>T p.R291W | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100760610; called by muse, mutect2, varscan2
- C6 | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54706107, COSV99667965; called by muse, mutect2
- CACNA1A | c.960G>T p.W320C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803427; called by muse, mutect2
- CACNA1H | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100673666, COSV61988583; called by muse, mutect2, varscan2
- CCDC158 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs1329795418, COSV101187423, COSV66355999; called by muse, mutect2, varscan2
- CCDC88A | c.3434A>T p.E1145V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99711363; called by muse, mutect2, varscan2
- CDCA5 | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV51870009, COSV99298084; called by muse, mutect2
- CDK12 | c.2848C>G p.R950G | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101420576; called by muse, mutect2, varscan2
- CDRT1 | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV55411073; called by muse, mutect2, varscan2
- CEP152 | c.3925C>T p.R1309* (on ENST00000380950 / NM_001194998.2; = p.R1253* on NM_014985.4) | Nonsense Mutation (SNP) | VAF 36/182 reads (20%) | catalogued as rs957548078, COSV57867334; called by muse, mutect2, varscan2
- CEP57 | c.598A>C p.T200P | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100334857; called by muse, mutect2, varscan2
- CES5A | c.551+1G>A p.X184_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as rs144674577, COSV51866498, COSV51867652; called by muse, varscan2
- CFAP20DC | c.1276G>T p.E426* (on ENST00000482387 / NM_001351530.2; = p.E301* on NM_198463.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV55916442, COSV99919695; called by muse, mutect2, varscan2
- CHD6 | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV100951399; called by muse, mutect2, varscan2
- CHL1 | c.1760G>T p.G587V (on ENST00000397491 / NM_001253387.1; = p.G603V on NM_006614.4) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849698; called by muse, mutect2, varscan2
- CHRM2 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV100282136; called by muse, mutect2, varscan2
- CLEC9A | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as rs754379977, COSV100191438; called by muse, mutect2, varscan2
- CMTR2 | c.307A>T p.R103* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100579395; called by muse, mutect2, varscan2
- CNTN4 | c.26T>A p.V9E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV101281759; called by muse, mutect2, varscan2
- COL6A2 | c.1865G>T p.S622I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100154448; called by muse, mutect2, varscan2
- COL6A6 | c.1828A>G p.I610V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100651084; called by muse, mutect2, varscan2
- COLEC12 | c.1995G>A p.W665* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV101232210; called by muse, mutect2, varscan2
- CSHL1 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99368311; called by muse, mutect2
- CSMD1 | c.10418C>A p.P3473Q (on ENST00000520002; = p.P3472Q on NM_033225.6) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100154850; called by muse, mutect2
- CSMD1 | c.6514G>T p.D2172Y (on ENST00000520002; = p.D2171Y on NM_033225.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100154852, COSV59294030; called by muse, mutect2, varscan2
- CYP20A1 | c.1187A>G p.K396R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV100619157; called by muse, mutect2, varscan2
- CYTH1 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV100739552; called by muse, mutect2, varscan2
- DACH1 | c.1591+1G>A p.X531_splice (on ENST00000619232 / NM_001366712.1; = p.X479_splice on NM_080759.6) | Splice Site (SNP) | VAF 9/62 reads (15%) | catalogued as COSV57501819; called by muse, mutect2, varscan2
- DDC | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100779836, COSV63564517; called by muse, mutect2, varscan2
- DENND5B | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100172396, COSV60908241; called by muse, mutect2, varscan2
- DHFR2 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 44/201 reads (22%) | catalogued as COSV100113517; called by muse, mutect2, varscan2
- DLGAP2 | c.2928G>A p.M976I | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV70104791; called by muse, mutect2, varscan2
- DOCK2 | c.5288C>T p.A1763V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.259); catalogued as rs1554130617, COSV99916176; called by muse, mutect2, varscan2
- EDN3 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767312223, COSV61111083; called by muse, mutect2, varscan2
- ESR2 | c.169A>C p.S57R | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV99964025; called by muse, mutect2, varscan2
- F8 | c.3280G>T p.E1094* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as CM141475, COSV64276788; called by muse, mutect2, varscan2
- FAM131B | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101281903; called by muse, mutect2, varscan2
- FAM98C | c.634-1G>C p.X212_splice | Splice Site (SNP) | VAF 24/149 reads (16%) | catalogued as COSV99385191; called by muse, mutect2, varscan2
- FBXL4 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.885); catalogued as COSV100014418; called by muse, mutect2, varscan2
- FOXA2 | c.835G>A p.G279R (on ENST00000377115 / NM_153675.3; = p.G285R on NM_021784.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101008545; called by muse, mutect2, varscan2
- FOXQ1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57259548, COSV99723366; called by muse, mutect2, varscan2
- FZD10 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs769513400, COSV99969664; called by muse, mutect2, varscan2
- FZD7 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.42); catalogued as COSV99637518; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.984); catalogued as rs1394415998, COSV100374611; called by muse, mutect2, varscan2
- GNA15 | c.830A>T p.N277I | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505493; called by muse, mutect2, varscan2
- GOLT1B | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV99982147; called by muse, mutect2, varscan2
- H1-8 | c.976A>T p.R326* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100140546; called by muse, mutect2, varscan2
- HOOK2 | c.1938G>T p.E646D | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99317894; called by muse, mutect2, varscan2
- HTN3 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV101126194; called by muse, mutect2, varscan2
- ICE1 | c.6020T>G p.L2007W | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV56831478, COSV99666000; called by muse, mutect2
- IGSF6 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99193671; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1811A>T p.H604L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.108); catalogued as COSV100151515; called by muse, mutect2, varscan2
- INAVA | c.1369A>T p.S457C | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100950156; called by muse, mutect2, varscan2
- ITGAD | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101210623; called by muse, mutect2, varscan2
- ITGBL1 | c.944C>A p.S315Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV101095910; called by muse, mutect2, varscan2
- ITSN1 | c.3184-1G>A p.X1062_splice | Splice Site (SNP) | VAF 14/107 reads (13%) | catalogued as COSV101180642; called by muse, mutect2, varscan2
- JAK1 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.991); catalogued as COSV100692572; called by muse, mutect2, varscan2
- KDM5C | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100855525; called by muse, mutect2, varscan2
- KIF26B | c.2265C>G p.S755R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100833634; called by muse, mutect2, varscan2
- KRT85 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99225764; called by muse, mutect2, varscan2
- KRTAP24-1 | c.71G>C p.C24S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100447565; called by muse, mutect2, varscan2
- L1CAM | c.2128C>A p.P710T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100649529; called by muse, mutect2, varscan2
- LCOR | c.1895G>A p.G632D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs757902954, COSV99617271; called by muse, mutect2, varscan2
- LIFR | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 51/756 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs781371324, COSV99665757; called by muse, mutect2
- LILRA6 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV99558729; called by muse, mutect2
- LONP1 | c.2557G>T p.G853C | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100028764; called by muse, mutect2, varscan2
- LRP1B | c.10646G>T p.C3549F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67218413; called by muse, mutect2
- LRP1B | c.10645T>A p.C3549S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV101262148; called by muse, mutect2
- LRRC2 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV56126672; called by muse, mutect2, varscan2
- LRRC30 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV101274473; called by muse, mutect2, varscan2
- LRRC40 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as COSV100918876, COSV63942437; called by muse, mutect2
- MCM4 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100031956; called by muse, mutect2, varscan2
- MED14 | c.1231C>G p.Q411E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100247680; called by muse, mutect2, varscan2
- MFSD9 | c.1273A>T p.I425F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV51495866, COSV99302355; called by muse, mutect2, varscan2
- MGA | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV99581983; called by muse, mutect2, varscan2
- MGMT | c.338C>G p.P113R (on ENST00000306010; = p.P82R on NM_002412.5) | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100024283; called by muse, mutect2
- MKI67 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100897084; called by muse, mutect2, varscan2
- MLNR | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267299634, COSV99520100; called by muse, mutect2
- MTARC2 | c.823A>T p.T275S | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100831096; called by muse, mutect2, varscan2
- MTMR12 | c.619A>C p.T207P | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99374187; called by muse, mutect2
- MUC16 | c.2446A>C p.T816P | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV101202120; called by muse, mutect2
- MUC4 | c.13355C>T p.T4452M (on ENST00000463781 / NM_018406.7; = p.T216M on NM_004532.6) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1386932761, COSV100206858; called by muse, mutect2, varscan2
- MYO16 | c.2948T>A p.I983N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV99194925; called by muse, mutect2, varscan2
- NAV3 | c.4033G>T p.V1345L | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.444); catalogued as COSV57063262, COSV99896682; called by muse, mutect2, varscan2
- NCAM2 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99525877; called by muse, mutect2, varscan2
- NEXMIF | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99282207; called by muse, mutect2, varscan2
- NLRP14 | c.3144A>T p.L1048= | Splice Region (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100205512; called by muse, mutect2, varscan2
- NLRX1 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99425035; called by muse, mutect2, varscan2
- NOX4 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.122); catalogued as COSV99632275; called by muse, mutect2, varscan2
- NPAP1 | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100276359; called by muse, mutect2
- NPAP1 | c.2975G>C p.G992A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.68); catalogued as rs763257404, COSV100276362, COSV61510981; called by muse, mutect2, varscan2
- NPHS1 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100800293, COSV62289829; called by muse, mutect2, varscan2
- NSMF | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99481686; called by muse, mutect2, varscan2
- OR10G8 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV101461892; called by muse, mutect2, varscan2
- OR13A1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100981117; called by muse, mutect2, varscan2
- OR1G1 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100187631; called by muse, mutect2, varscan2
- OR2C3 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV63576601; called by muse, mutect2, varscan2
- OR51Q1 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100333114; called by muse, mutect2, varscan2
- OR52I1 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100331861; called by muse, mutect2, varscan2
- OR5K1 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100221057, COSV60304251; called by muse, mutect2, varscan2
- OR5L1 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs142577076, COSV61733414, COSV61735814; called by muse, mutect2, varscan2
- OR8J1 | c.381T>A p.C127* | Nonsense Mutation (SNP) | VAF 45/172 reads (26%) | catalogued as COSV100275284; called by muse, mutect2, varscan2
- OR8J3 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100041095; called by muse, mutect2, varscan2
- PAPPA2 | c.2563C>G p.Q855E | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100867260; called by muse, mutect2, varscan2
- PAX5 | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100814674; called by muse, mutect2, varscan2
- PCDH11X | c.3811C>A p.Q1271K | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as COSV100016099; called by muse, mutect2, varscan2
- PCDHGA10 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.117); catalogued as COSV99549035; called by muse, mutect2, varscan2
- PCSK5 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950829; called by muse, mutect2, varscan2
- PDZD2 | c.7388A>G p.K2463R | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99227168; called by muse, mutect2
- PLAG1 | c.198A>C p.Q66H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV57609053; called by muse, mutect2, varscan2
- PLIN1 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as rs1307383766, COSV100261790; called by muse, mutect2, varscan2
- PLOD3 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV99778356; called by muse, mutect2
- POGLUT2 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV99959192; called by muse, mutect2, varscan2
- POLR1F | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99749135; called by muse, mutect2, varscan2
- POLR1F | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV99749141; called by muse, mutect2, varscan2
- PPFIA2 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780679502, COSV100335595; called by muse, mutect2
- PPIL2 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1303838586, COSV100622422, COSV100622669; called by muse, mutect2
- PRB4 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 112/598 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.053); catalogued as rs779318469, COSV99686906; called by muse, mutect2, varscan2
- PRG3 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99756187; called by muse, mutect2
- PRKAG3 | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99292169; called by muse, mutect2, varscan2
- PSPN | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99831816; called by muse, mutect2, varscan2
- RAD54L2 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV99621978; called by muse, mutect2, varscan2
- RALGAPA1 | c.2765G>T p.R922L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV99352821; called by muse, mutect2, varscan2
- RCC2 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100965214; called by muse, mutect2, varscan2
- REG1B | c.334C>G p.H112D | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100521554; called by muse, mutect2, varscan2
- RFX3 | c.769A>C p.K257Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100176036; called by muse, varscan2
- RIMS2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV68492134; called by muse, mutect2
- SCN3A | c.2645T>C p.L882P | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328885; called by muse, mutect2, varscan2
- SGK2 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100414882, COSV58315277; called by muse, mutect2, varscan2
- SIK3 | c.3568G>A p.E1190K (on ENST00000445177 / NM_001366686.2; = p.E1148K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV52624170, COSV99408395; called by muse, mutect2
- SIM1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53491472, COSV99492931; called by muse, mutect2, varscan2
- SIPA1L2 | c.3493G>T p.G1165* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99479947; called by muse, mutect2
- SIPA1L3 | c.2923G>T p.G975W | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729761, COSV99730817; called by muse, mutect2, varscan2
- SIPA1L3 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99730819; called by muse, mutect2, varscan2
- SLC25A43 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV99474819; called by muse, mutect2, varscan2
- SLC35F1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100837747, COSV64498307; called by muse, mutect2, varscan2
- SLC49A3 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100448588; called by muse, mutect2, varscan2
- SLC52A1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs147698089; called by muse, mutect2, varscan2
- STIL | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99681437; called by muse, mutect2, varscan2
- SYCP2L | c.1103A>T p.Y368F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV99305971; called by muse, mutect2, varscan2
- SYF2 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752330138, COSV99360165; called by muse, mutect2, varscan2
- SYNE1 | c.4376C>A p.S1459Y (on ENST00000367255 / NM_182961.4; = p.S1466Y on NM_033071.3) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99583452; called by muse, mutect2, varscan2
- SYTL2 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs1197229100, COSV100315082; called by muse, mutect2, varscan2
- TARS3 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255095; called by muse, mutect2, varscan2
- TAS2R5 | c.637C>G p.R213G | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs149987830, COSV99924874; called by muse, mutect2, varscan2
- TBCA | c.246A>G p.L82= | Splice Region (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100116299, COSV60538588; called by muse, mutect2, varscan2
- TCHHL1 | c.1231A>G p.K411E | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs775138435, COSV100916639; called by muse, mutect2, varscan2
- TDRD3 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV99541360; called by muse, mutect2, varscan2
- TEKT4 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99726819; called by muse, mutect2, varscan2
- TENM4 | c.4847G>T p.G1616V | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV99580546; called by muse, mutect2, varscan2
- TENM4 | c.4846G>T p.G1616C | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV53637220, COSV99580548; called by muse, mutect2, varscan2
- TF | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV99396527; called by muse, mutect2, varscan2
- THBS2 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100828146; called by muse, mutect2, varscan2
- TLCD3B | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV99662625; called by muse, mutect2
- TLCD4 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1168501021, COSV100930801; called by muse, mutect2, varscan2
- TNNI3 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100788046; called by muse, mutect2, varscan2
- TNNI3K | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99632443; called by muse, mutect2, varscan2
- TOGARAM2 | c.2573C>A p.S858Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101091565; called by muse, mutect2, varscan2
- TSHZ1 | c.2359T>G p.Y787D (on ENST00000580243 / NM_001308210.2; = p.Y742D on NM_005786.6) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs200217009, COSV100433975; called by muse, mutect2, varscan2
- TTI1 | c.1448G>C p.R483T | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV100989787; called by muse, mutect2
- TUBB8 | c.1244T>A p.M415K | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as COSV100226225; called by muse, mutect2, varscan2
- UBAP1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV52659896; called by muse, mutect2, varscan2
- USP22 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs372666473; called by muse, mutect2, varscan2
- UVSSA | c.1429G>C p.A477P | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV101104635; called by muse, mutect2, varscan2
- WDR92 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54562034; called by muse, mutect2, varscan2
- ZHX2 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100072874, COSV100073762, COSV100074060; called by muse, mutect2, varscan2
- ZNF337 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99430578; called by muse, mutect2, varscan2
- ZNF367 | c.460del p.R154Afs*3 | Frame Shift Del (DEL) | VAF 40/208 reads (19%) | catalogued as COSV64547879; called by mutect2, pindel, varscan2
- ZNF441 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.127); catalogued as COSV100777468; called by muse, mutect2, varscan2
- ZNF513 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99278118; called by muse, mutect2, varscan2
- ZNF613 | c.466G>T p.G156W (on ENST00000293471 / NM_001031721.4; = p.G120W on NM_024840.4) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV99523102; called by muse, mutect2, varscan2
- ZPBP | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs375766793; called by muse, mutect2, varscan2
- ARID1A | c.4130_4131del p.Y1377Wfs*67 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by pindel, varscan2
- CFAP52 | c.843C>A p.Y281* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- HAVCR2 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP10-11 | c.159_160del p.S54Qfs*9 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by pindel, varscan2
- LSM8 | c.32-6_39del p.X11_splice | Splice Site (DEL) | VAF 9/88 reads (10%) | called by mutect2, pindel
- PRCP | c.1275C>T p.S425= | Splice Region (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PRKG1 | c.1338_1347del p.K447Ifs*3 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | called by mutect2, pindel
- RASA1 | c.2972_2977del p.L991_S992del | In Frame Del (DEL) | VAF 37/193 reads (19%) | called by mutect2, pindel, varscan2
- RSPH6A | c.1493del p.G498Afs*60 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by pindel, varscan2
- SERPINI2 | c.682dup p.S228Ffs*2 | Frame Shift Ins (INS) | VAF 15/136 reads (11%) | called by mutect2, pindel, varscan2
- SETBP1 | c.3724dup p.W1242Lfs*13 | Frame Shift Ins (INS) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- TP53 | c.658_672+5del p.X220_splice | Splice Site (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel
- TRAV5 | c.203C>G p.T68R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- UGGT2 | c.920_921delinsT p.W307Lfs*14 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | called by pindel, varscan2*
- AC004922.1 | c.1488C>T p.F496= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as COSV99403154; called by muse, mutect2, varscan2
- ACVR1C | c.69G>T p.S23= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1056883913, COSV99695174; called by muse, mutect2, varscan2
- ADGRB3 | c.2574C>T p.T858= | Silent (SNP) | VAF 35/199 reads (18%) | catalogued as rs1267103534, COSV99487212; called by muse, mutect2, varscan2
- AKT3 | c.459A>G p.L153= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99797236; called by muse, mutect2, varscan2
- ANK2 | c.9579A>T p.I3193= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100004707; called by muse, mutect2, varscan2
- APOB | c.5283C>T p.G1761= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as rs1206881668, COSV51925743, COSV99268639; called by muse, mutect2, varscan2
- AVPR1A | c.645C>A p.A215= | Silent (SNP) | VAF 43/213 reads (20%) | catalogued as COSV100146932; called by muse, mutect2, varscan2
- BEND3 | c.2124C>T p.V708= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as COSV100944712; called by muse, mutect2, varscan2
- CARD6 | c.210G>A p.A70= | Silent (SNP) | VAF 156/224 reads (70%) | catalogued as rs898679571, COSV99621422; called by muse, mutect2, varscan2
- CCDC158 | c.1272G>T p.R424= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV101187421; called by muse, mutect2, varscan2
- CHMP1B | c.33G>C p.L11= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1366922553, COSV99304337; called by muse, mutect2, varscan2
- CHST8 | c.426G>T p.L142= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99381781; called by muse, mutect2, varscan2
- CLCA4 | c.2205C>T p.S735= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs754468914, COSV100991232; called by muse, mutect2, varscan2
- CNGB3 | c.1527C>A p.A509= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100183289; called by muse, mutect2, varscan2
- COL11A1 | c.2334T>A p.G778= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100618322; called by muse, mutect2, varscan2
- CR1 | c.5136T>C p.D1712= | Silent (SNP) | VAF 67/410 reads (16%) | catalogued as COSV100888096; called by muse, mutect2, varscan2
- DENND3 | c.1797G>T p.T599= | Silent (SNP) | VAF 72/203 reads (35%) | catalogued as COSV52805547, COSV99371658; called by muse, mutect2, varscan2
- DOCK11 | c.1125T>C p.T375= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV99355004; called by muse, mutect2, varscan2
- EMC10 | c.160C>T p.L54= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100618567; called by muse, mutect2, varscan2
- EXPH5 | c.1165C>T p.L389= | Silent (SNP) | VAF 68/291 reads (23%) | catalogued as rs1242715935, COSV99762372; called by muse, mutect2, varscan2
- FAM234B | c.282G>C p.A94= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV99546064; called by muse, mutect2, varscan2
- FAT3 | c.11940C>T p.S3980= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs941926637, COSV53079872, COSV53166218; called by muse, mutect2, varscan2
- FBXO28 | c.939A>G p.Q313= | Silent (SNP) | VAF 53/293 reads (18%) | catalogued as rs746911613, COSV100837502; called by muse, mutect2, varscan2
- FOXI1 | c.1128C>A p.T376= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100089659; called by muse, mutect2, varscan2
- GABRB3 | c.192G>A p.T64= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as rs370850076; called by muse, mutect2, varscan2
- GTF3C2 | c.2277G>C p.L759= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99273399; called by muse, mutect2, varscan2
- HDAC6 | c.318G>T p.P106= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100491270; called by muse, mutect2, varscan2
- HOOK1 | c.234A>G p.V78= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100969289; called by muse, mutect2, varscan2
- IRX1 | c.423G>T p.T141= | Silent (SNP) | VAF 24/326 reads (7%) | catalogued as rs774834953, COSV100116865; called by muse, mutect2
- ITGBL1 | c.945C>A p.S315= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV101095912; called by muse, mutect2, varscan2
- KIF2C | c.2026C>T p.L676= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs370355160; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1647G>T p.V549= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99169895; called by muse, mutect2
- MFSD9 | c.1272C>A p.I424= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99302357; called by muse, mutect2, varscan2
- MMP17 | c.498C>A p.V166= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV100861998; called by muse, mutect2, varscan2
- MYO1F | c.162C>T p.L54= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as rs1224460359, COSV100597174; called by muse, mutect2, varscan2
- NPTX1 | c.1242C>T p.I414= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs146777310, COSV100151221, COSV60776985; called by muse, mutect2, varscan2
- NRXN1 | c.444G>T p.T148= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV101280856, COSV68022177; called by muse, mutect2, varscan2
- NWD1 | c.681C>G p.L227= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV100342160; called by muse, mutect2, varscan2
- OR2M2 | c.666T>C p.I222= | Silent (SNP) | VAF 52/364 reads (14%) | catalogued as rs1268391572, COSV62898610; called by muse, mutect2
- OR52E8 | c.147T>C p.T49= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as rs1393425086, COSV101191247; called by muse, mutect2, varscan2
- PCDHA8 | c.1536G>A p.T512= | Silent (SNP) | VAF 72/271 reads (27%) | catalogued as COSV65331912; called by muse, mutect2, varscan2
- PLEKHG1 | c.1575G>T p.A525= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100651962; called by muse, mutect2, varscan2
- PLSCR5 | c.129T>C p.P43= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs751963795, COSV101494518; called by muse, mutect2, varscan2
- PNISR | c.198T>C p.D66= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV100984446; called by muse, mutect2, varscan2
- RASSF2 | c.213G>A p.Q71= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs1249266732, COSV65082311; called by muse, mutect2, varscan2
- RCSD1 | c.864T>A p.S288= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1225490583, COSV100827819; called by muse, mutect2, varscan2
- RGS6 | c.276C>G p.G92= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100667212; called by muse, mutect2, varscan2
- RP1 | c.5415C>G p.L1805= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55109911, COSV99609156; called by muse, mutect2, varscan2
- RUBCN | c.141C>G p.V47= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV99585307; called by muse, mutect2, varscan2
- SCAF11 | c.1386A>T p.A462= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV101014740; called by muse, mutect2, varscan2
- SERPINA9 | c.744T>C p.F248= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100098957; called by muse, mutect2, varscan2
- SH3BP5L | c.774C>T p.S258= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100822134; called by muse, mutect2, varscan2
- SIK2 | c.1038G>A p.V346= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as COSV100516538; called by muse, mutect2, varscan2
- SLC52A1 | c.561C>T p.F187= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV99643579; called by muse, mutect2, varscan2
- SND1 | c.84C>T p.L28= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100691300; called by muse, varscan2
- TAAR5 | c.282C>G p.R94= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs1252584405, COSV99237024; called by muse, mutect2, varscan2
- TBC1D24 | c.273G>A p.P91= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as rs762804146, COSV53549461; called by muse, mutect2
- THBS2 | c.144C>A p.P48= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100828145, COSV64682168; called by muse, mutect2, varscan2
- THEG | c.180A>G p.P60= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as COSV100700678; called by muse, mutect2, varscan2
- TMEM132D | c.3159C>T p.V1053= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV101243132, COSV67158839; called by muse, mutect2, varscan2
- UBR4 | c.13593C>T p.N4531= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100922125; called by muse, mutect2, varscan2
- UTP14C | c.627C>G p.A209= | Silent (SNP) | VAF 52/179 reads (29%) | catalogued as COSV101584409; called by muse, mutect2, varscan2
- ZC3H14 | c.1062G>T p.L354= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99193323; called by muse, mutect2, varscan2
- ZCCHC2 | c.2232T>C p.D744= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99502758; called by muse, mutect2, varscan2
- ZNF264 | c.1476C>T p.F492= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs1439150762, COSV99567468; called by muse, mutect2, varscan2
- ZNF479 | c.1494T>C p.C498= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100483168; called by muse, mutect2, varscan2
- ZNF695 | c.252A>G p.R84= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100377807; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668455 C>A | 5'Flank (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- CCDC159 | c.22-529C>T | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs1204188484; called by muse, mutect2, varscan2
- DNAH8 | chr6:38723119 C>T | 5'Flank (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100547436; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.205C>T | RNA (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- NFASC | c.91+2304T>G | Intron (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100366156; called by muse, mutect2, varscan2
- SH3GL3 | c.45+43311G>T | Intron (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100197822; called by muse, mutect2, varscan2
- SH3GL3 | c.45+43312G>T | Intron (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100197823; called by muse, mutect2, varscan2
- SORBS2 | c.685-7555A>T | Intron (SNP) | VAF 36/154 reads (23%) | catalogued as COSV99513199; called by muse, mutect2, varscan2
- TBCE | c.372-3531G>T | Intron (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100783309; called by muse, mutect2, varscan2
- TTN | c.10361-5103C>T | Intron (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100634649; called by muse, mutect2, varscan2
